Somatic mutation profile of tumor specimen MP2PRT-PAPFYD-TMP1-A (aliquot MP2PRT-PAPFYD-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PAPFYD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Precursor cell lymphoblastic leukemia, not phenotyped; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.0 years (2,937 days).
Specimen MP2PRT-PAPFYD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8045e5ab-0f36-442c-a49f-9d6dfbf6e6d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPFYD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPFYD-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/454468ee-6843-4ba0-9d2c-249c8030df22

The open-access MAF lists 14 somatic variants for this specimen: 5 protein-altering or splice-affecting, 9 silent.
By variant classification: Silent 9, Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHAT | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 142/391 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912822, CM014854, COSV100339471; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MKS1 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 110/257 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.132); catalogued as rs181513926, COSV99836259; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNA3 | c.4216C>T p.R1406C | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs187722897; called by muse, mutect2
- MACC1 | c.566C>A p.A189D | Missense Mutation (SNP) | VAF 18/440 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2
- ROM1 | c.989G>T p.C330F | Missense Mutation (SNP) | VAF 35/447 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- C1QTNF9 | c.297A>G p.K99= | Silent (SNP) | VAF 42/84 reads (50%) | called by muse, mutect2, varscan2
- C1QTNF9B | c.297A>G p.K99= | Silent (SNP) | VAF 148/807 reads (18%) | called by muse, mutect2, varscan2
- EPC2 | c.1239G>A p.L413= | Silent (SNP) | VAF 18/373 reads (5%) | called by muse, mutect2
- GDF7 | c.1092C>T p.D364= | Silent (SNP) | VAF 290/676 reads (43%) | catalogued as rs202010435; called by muse, mutect2, varscan2
- IL20RA | c.1053T>C p.P351= | Silent (SNP) | VAF 24/539 reads (4%) | called by muse, mutect2
- PDE4B | c.51A>G p.K17= | Silent (SNP) | VAF 99/264 reads (38%) | called by muse, mutect2, varscan2
- PLCL1 | c.1323C>T p.S441= | Silent (SNP) | VAF 17/378 reads (4%) | catalogued as rs1433754909, COSV70870981; called by muse, mutect2
- PTCHD3 | c.153G>T p.P51= | Silent (SNP) | VAF 20/562 reads (4%) | catalogued as COSV71256764, COSV71257170; called by muse, mutect2
- PTPRG | c.129C>T p.H43= | Silent (SNP) | VAF 200/448 reads (45%) | catalogued as rs112845451; called by muse, mutect2
